TCGA case TCGA-13-0893 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/15170c7f-5880-4fb6-82ce-68d3df0dfb68

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Dead; Days to death: 1,319 days (3.6 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 48.1 years (17,573 days); Year of diagnosis: 2003; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 11-20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 80 days; Days to treatment end: 284 days; Number of cycles: 8; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 80 days; Days to treatment end: 284 days; Number of cycles: 8; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Adjuvant; Days to treatment start: 340 days; Days to treatment end: 566 days (1.5 years); Treatment dose: 3 mg/m2.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 49.4 years (18,034 days); Days to diagnosis: 461 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 461 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 461 days (1.3 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,319 days (3.6 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-0893-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-13-0893-01B-01-BS1: Section location: Bottom; Percent tumor cells: 89; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 10.
  Slide TCGA-13-0893-01B-01-TS1: Section location: Top; Percent tumor cells: 89; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 10.
- Sample TCGA-13-0893-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 1: Pharmaceutical therapy drug name: Paciltaxel.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Femara.
- Follow-up form: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,319 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,319 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 461 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-13-0893-01B-01D-0452-01): tumor purity 0.71, ploidy 3.27, whole-genome doublings 1.
